FM case AD1494 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/81aff98d-fc03-4ccc-83c9-3ad89758d5a1

Male, 73.9 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
